Gene-level copy-number profile of tumor specimen HCM-CSHL-0467-C56-06A from HCMI case HCM-CSHL-0467-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; AJCC pathologic stage: Stage IIIC; FIGO stage: Stage III; Tumor grade: High Grade.
Specimen HCM-CSHL-0467-C56-06A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 456e9f01-a1e3-4530-8772-b33cd92df583.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0467-C56-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/c9cb5f10-bb49-4383-a43f-ccf89ec94a5e

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 17; copy number 1: 3,711; copy number 2: 21,327; copy number 3: 21,998; copy number 4: 7,196; copy number 5: 3,011; copy number 6: 314; copy number 7: 305; copy number 8: 330; copy number 9: 2; copy number 10: 170; copy number 11: 1; copy number 12: 14.

Homozygous deletions (total copy number 0; autosomes only): 17 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr8:12,362,019–12,388,296, 3 genes: FAM66A, AC087203.1, AC087203.2.
- chr9:29,636,486–29,826,711, 2 genes: AL354676.1, ME2P1.
- chr11:55,602,360–55,666,195, 4 genes: OR4C11, OR4P4, OR4S2, OR4C6.
- chr14:44,444,747–44,480,626, 1 gene: LINC02277.
- chr22:18,855,621–18,894,407, 3 genes (within-gene range 0–1): BCRP7, FAM230F, AC008103.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 822 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:60,336,446–62,171,163, 54 genes, copy number 7: MIR4432HG, AC007381.1, RNU1-32P, MIR4432, BCL11A, AC009970.1, RN7SL361P, IFITM3P9, RPL26P13, RNU6-612P, ATP1B3P1, PAPOLG, LINC01185, RN7SL632P, RPL21P33, REL, RNU4-51P, AC010733.1, NONOP2, RPS12P3, PUS10, RNA5SP95, PEX13, KIAA1841, AC016747.4, AC016747.1, C2orf74, AC016747.2, AHSA2P, USP34, AC016747.3, AC018889.1, AC016894.1, SNORA70B, AC016727.1, XPO1, AC016727.3, AC016727.2, RPS29P10, RNU6-1145P, AC108039.1, RPS24P7, AC108039.2, FAM161A, RPL31P30, AC107081.2, CCT4, AC107081.1, AC107081.3, COMMD1, Y_RNA, AC018462.1, RPSAP26, AC018462.2.
- chr2:111,429,324–114,420,302, 91 genes, copy number 7–10 (within-gene range 2–10) (broad region; genes not listed).
- chr2:170,178,145–170,655,171, 1 gene, copy number 7 (within-gene range 4–7): MYO3B.
- chr2:170,601,662–171,999,859, 27 genes, copy number 7 (within-gene range 5–7): HMGB1P4, AC007277.1, AC007277.2, AC007405.1, LINC01124, SP5, EIF2S2P4, AC007405.3, Y_RNA, ERICH2, GAD1, AC007405.2, AC007405.4, GORASP2, TLK1, METTL8, RPS26P20, DCAF17, DAP3P2, AC007969.1, RPS15P4, CYBRD1, RPL21P38, DYNC1I2, SLC25A12, RNU6-182P, HAT1.
- chr3:75,370,448–75,590,649, 12 genes, copy number 7: OR7E55P, AC139453.2, LSP1P2, AC139453.1, ALG1L6P, FAM86DP, LINC02018, ENPP7P2, SNRPCP10, AC133041.1, RPS3AP15, AC108724.1.
- chr5:70,751,184–70,795,914, 2 genes, copy number 9: GUSBP16, AC139272.1.
- chr5:70,925,030–71,025,339, 3 genes, copy number 7: SMN1, AC139834.1, NAIP.
- chr5:71,102,898–71,133,287, 2 genes, copy number 8: NAIPP4, CDH12P4.
- chr5:97,737,894–97,738,913, 1 gene, copy number 7: AC112203.1.
- chr6:170,615,515–170,738,536, 1 gene, copy number 8 (within-gene range 4–10): AL672310.1.
- chr6:170,695,313–170,737,777, 2 genes, copy number 8–10: AL731661.1, AL731684.1.
- chr14:22,132,553–22,482,346, 36 genes, copy number 7 (within-gene range 5–7): TRAV8-7, TRAV27, TRAV28, TRAV29DV5, TRAV30, TRAV31, TRAV32, TRAV33, TRAV26-2, TRAV34, TRAV35, TRAV36DV7, TRAV37, TRAV38-1, TRAV38-2DV8, TRAV39, TRAV40, TRAV41, AC244502.2, AC244502.3, TRDV2, TRDD1, TRDD2, TRDJ4, TRDJ2, TRDJ3, TRDC, TRDV3, TRAJ61, TRAJ60, TRAJ59, TRAJ58, TRAJ57, TRAJ56, TRAJ55, TRAJ54.
- chr14:22,547,506–22,552,156, 1 gene, copy number 7: TRAC.
- chr19:12,763,003–12,872,740, 1 gene, copy number 10 (within-gene range 2–10): HOOK2.
- chr19:12,787,128–13,633,025, 40 genes, copy number 10: MIR5684, JUNB, PRDX2, AC018761.2, THSD8, RNASEH2A, RTBDN, AC020934.1, MAST1, MIR6794, DNASE2, AC020934.2, KLF1, GCDH, RPS6P25, SYCE2, MIR5695, FARSA, FARSA-AS1, CALR, MIR6515, AC092069.1, RAD23A, GADD45GIP1, DAND5, NFIX, AC138474.1, AC007787.1, AC007787.2, LYL1, TRMT1, NACC1, AC005546.1, AC011446.1, STX10, IER2, AC011446.3, AC011446.2, RPL12P42, CACNA1A.
- chr20:38,805,697–59,847,711, 431 genes, copy number 8–12 (broad region; genes not listed).
- chr20:62,410,237–64,327,972, 117 genes, copy number 7 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,367. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
